Somatic mutation profile of tumor specimen BA2996D (aliquot aq-BA2996D) from BEATAML1.0 case 2272, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.2 years (23,450 days).
Specimen BA2996D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b86729bd-6384-4e56-a977-d47e9f0430ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2299D (Solid Tissue Normal), aliquot aq-BA2299D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16314942-b223-4a5b-a4c6-02d961cdc454

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IZUMO1R | c.328G>A p.V110M (on ENST00000440961; = p.V117M on NM_001199206.3) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as rs1414161730; called by muse, mutect2, varscan2
- TGFBR2 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 40/451 reads (9%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.581); catalogued as rs1553631704, COSV55445508; ClinVar: uncertain significance; called by muse, mutect2
- USP30 | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.213); catalogued as rs1407461382; called by muse, mutect2
- SLC36A4 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- TSPYL5 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); called by muse, mutect2
- DDX41 | c.*334G>C | 3'UTR (SNP) | VAF 10/152 reads (7%) | catalogued as COSV57252016; called by muse, mutect2
- NAA20 | c.53+582T>G | Intron (SNP) | VAF 11/253 reads (4%) | called by muse, mutect2
